Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A87T, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A87T-01A (Primary Tumor).

Accession:
Specimen Date/Time:

IOD-03
Melanoma, spindle cell, type B 877413
Site: B Choroid C69.3
AJ 1/16/14

DIAGNOSIS

(A) RIGHT GLOBE, ENUCLEATION:

(> 90%)
CHOROIDAL MELANOMA (11 MM BASE) SPINDLE TYPE B. (See comment)
SUPERFICIAL SCLERAL INVASION IS PRESENT.

The tumor is confined to the globe, extraocular extension is not identified.

Vortex vein invasion is not identified.

The optic nerve is uninvolved.

Lens with nuclear sclerosis

Entire report and diagnosis completed by

COMMENT

The tumor is amelanotic and shows focal complex vortex veins by PAS. The retina over the tumor is thin and atrophic with loss of retina over a portion of the tumor. The retina shows detachment near the base of the tumor. The tumor shows mitotic activity at two per 10 high power fields.

GROSS DESCRIPTION

(A) RIGHT GLOBE - A firm intact right eye (23.0 mm AP x 23.0 mm horizontal x 22.0 mm vertical) has attached optic nerve (4.0 mm in length). The cornea is transparent (11.0 mm horizontal x 10.0 mm vertical). The anterior chamber is formed surrounded by a blue-gray iris with a round 5.0 mm in diameter pupil. The sclera is unremarkable. On transillumination, a shadow 8.0 mm from the limbus is present from 2-4 o'clock hours and extends to 5 mm from the optic nerve. The shadow corresponds to a tan tumor with a 11 mm base and a height of 10 mm. The vertical growth is mushrooming with the top larger than the base. On sectioning, the tumor is free from the optic nerve located 8 mm from this area. The sclera is grossly intact. The optic nerve head is unremarkable. Tissue was harvested from an inferior clot.

SECTION CODE: A1, superior temple vortex vein; A2, superior nasal vortex vein; A3, inferior nasal vortex vein; A4, inferior temporal vortex vein; A5, optic nerve cross section; A6, pupil optic nerve section; A7, superior calottes; A8, inferior calotte.

CLINICAL HISTORY

Uveal melanoma, right eye.

SNOMED CODES

T-AA000, M-87203

"Some tests reported here may have been developed and performance characteristics determined by

These tests have not been

specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

-----END OF REPORT-----

ICDAR Discrepancy		
Date is (circle)		

hw 10/25/13
10/2/13

Source: NCI Genomic Data Commons file 30306d34-181a-4c0b-a262-aa5f5ce9224b (TCGA-WC-A87T.C97D9B9F-544A-471A-9F51-88389EC7630C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).